CCDI case PBBPUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/286e21fc-0500-4716-9d78-1884ec4ed580

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.2 years (5,563 days).

Biospecimens (3 samples)
- Sample 0DFKH3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFKH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFKH5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
